Somatic mutation profile of tumor specimen 0DLV3N from CCDI case PBBZTL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 14.5 years (5,312 days).
Specimen 0DLV3N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a30bf89-36ba-4c30-b70c-f3922bb3621f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLV2Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5185866-4acb-45f3-829a-4e73acc28b06

The open-access MAF lists 39 somatic variants for this specimen: 12 protein-altering or splice-affecting, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 19, Missense Mutation 8, 3'UTR 6, Splice Site 2, 5'UTR 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5532G>C p.K1844N | Missense Mutation (SNP) | VAF 32/790 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1360182417; called by muse, mutect2
- PCNX3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 168/687 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.232); catalogued as rs773286636; called by muse, mutect2, varscan2
- SEMA3G | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 200/684 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs143787641; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 49/432 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 34/257 reads (13%) | called by muse, varscan2
- GLO1 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 56/450 reads (12%) | called by muse, varscan2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 55/443 reads (12%) | called by muse, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 62/1166 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 38/777 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- RIPK2 | c.599C>G p.P200R | Missense Mutation (SNP) | VAF 52/548 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, varscan2
- RTL1 | c.3085G>T p.E1029* | Nonsense Mutation (SNP) | VAF 123/528 reads (23%) | called by muse, mutect2, varscan2
- VPS13A | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 72/698 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 23/164 reads (14%) | called by muse, varscan2
- BPNT1 | c.*35T>C | 3'UTR (SNP) | VAF 34/522 reads (7%) | catalogued as rs1372238489, COSV59039295; called by muse, mutect2
- C3orf49 | c.849+99T>C | Intron (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 19/277 reads (7%) | called by muse, mutect2
- CEP112 | c.2697+92T>C | Intron (SNP) | VAF 26/198 reads (13%) | called by muse, mutect2
- CEP290 | c.495+46A>T | Intron (SNP) | VAF 43/362 reads (12%) | called by muse, varscan2
- CLEC3A | c.*77C>T | 3'UTR (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 45/409 reads (11%) | called by muse, varscan2
- DLG5 | c.3403-70T>C | Intron (SNP) | VAF 22/296 reads (7%) | called by muse, mutect2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 22/210 reads (10%) | called by muse, varscan2
- GGNBP2 | c.1215+86G>A | Intron (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 18/131 reads (14%) | called by muse, varscan2
- IMMT | c.421+95T>C | Intron (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- LARP4 | c.1334+89G>T | Intron (SNP) | VAF 10/118 reads (8%) | called by mutect2, varscan2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 24/303 reads (8%) | catalogued as rs1415560984; called by mutect2, varscan2
- NAV1 | c.3406-50T>C | Intron (SNP) | VAF 47/484 reads (10%) | catalogued as rs1183848014; called by muse, mutect2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 22/344 reads (6%) | called by muse, mutect2
- PNO1 | c.621-73T>C | Intron (SNP) | VAF 26/267 reads (10%) | catalogued as COSV55152537; called by muse, mutect2
- PRRG4 | c.*62T>C | 3'UTR (SNP) | VAF 32/648 reads (5%) | catalogued as rs1283154682; called by muse, mutect2
- PSIP1 | c.149+38T>C | Intron (SNP) | VAF 135/533 reads (25%) | called by muse, mutect2, varscan2
- PTRH1 | c.*318A>G | 3'UTR (SNP) | VAF 36/578 reads (6%) | catalogued as COSV100077227; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 40/262 reads (15%) | called by muse, varscan2
- SPINT2 | c.391+51G>A | Intron (SNP) | VAF 26/252 reads (10%) | catalogued as rs749337905; called by muse, mutect2
- SPTLC1 | c.427+88C>A | Intron (SNP) | VAF 23/174 reads (13%) | catalogued as rs965501697, COSV104391182; called by muse, mutect2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, varscan2
- ZP3 | c.714-64T>C | Intron (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
